Surgical pathology report (de-identified scan), TCGA case TCGA-61-1914, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1914-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED ADENOCARCINOMA WITH PAPILLARY FEATURES INVOLVING OVARY, FALLOPIAN TUBE AND SURROUNDING SOFT TISSUE.
- B. LYMPHOVASCULAR INVASION IDENTIFIED.

PART 2: UTERUS AND RIGHT ADNEXUM, TOTAL ABDOMINAL HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED ADENOCARCINOMA WITH PAPILLARY FEATURES, INVOLVING THE RIGHT OVARY AND CORTICAL ADHESIONS.
- B. MULTIPLE LEIOMYOMATA UP TO 4.0 CM IN DIAMETER.
- C. ADENOMYOSIS.
- D. CHRONIC CERVICITIS.
- E. ATROPHY OF ENDOMETRIUM.
- F. UNREMARKABLE RIGHT FALLOPIAN TUBE.

PART 3: OMENTUM, OMENTECTOMY -

EXTENSIVE POORLY DIFFERENTIATED ADENOCARCINOMA WITH PAPILLARY FEATURES AND PSAMMOMA BODIES.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

- A. Laterality: 3
- 1. Right
- 2. Left
- 3. Bilateral
- B. Procedure: 4
- 1. Cystectomy
- 2. Salpingo-oophorectomy
- 3. Bilateral salpingo-oophorectomy
- 4. TAH with salpingo-oophorectomy
- 5. Other
- C. Tumor size (maximum dimension): # cm
- D. Histologic type: 2
- 1. Papillary serous tumor, ☒ *
- 2. Papillary serous carcinoma
- 3. Mucinous tumor, ☒
- 4. Mucinous carcinoma
- 5. Endometrioid tumor, ☒
- 6. Endometrioid carcinoma
- 7. Clear cell tumor, ☒
- 8. Clear cell carcinoma
- 9. Brenner tumor, ☒
- 10. Malignant Brenner tumor
- 11. Malignant mixed Müllerian tumor
- 12. Undifferentiated Carcinoma
- 13. Small cell carcinoma
- 14. Mature teratoma
- 15. Immature teratoma
- 16. Dysgerminoma
- 17. Embryonal carcinoma
- 18. Yolk sac tumor
- 19. Granulosa cell tumor, Juvenile
- 20. Granulosa cell tumor, adult
- 21. Malignant lymphoma
- 22. Others
- E. Histologic Grade: 3
- 1. Well
- 2. Moderate
- 3. Poorly differentiated
- F. Vascular Invasion: 1
- 1. Yes
- 2. No
- G. Tumor capsule: 2
- 1. Intact
- 2. Ruptured
- H. Surface implants: 1
- 1. Invasive
- 2. Non-invasive
- 3. Not present
- I. Surface implants:
- I1. Uterus: 2
- 1. Yes
- 2. No
- I2. Fallopian tubes: 1
- 1. Yes
- 2. No
- I3. Omentum: 1
- 1. Yes
- 2. No
- I4. Peritoneal metastasis beyond the pelvis: 3
- 1. Microscopic
- 2. Less than 2 cm.
- 3. More than 2 cm.
- J. Associated other lesion: # / # / #
- 1. Endometriosis.
- 2. Abnormalities of surface epithelium or surface epithelial inclusion.
- 3. Others.
- K. Malignant cells in ascites or peritoneal washing: 1
- 1. Yes
- 2. No
- L. Nodes Involved: #
- L1. Number of positive lymph nodes: #
- L2. Total number of lymph nodes examined: #
- L3. Pelvic: Right: # positive/total # Left: # positive/total #
- L4. Obturator: Right: # positive/total # Left: # positive/total #
- L5. Common iliac: Right: # positive/total # Left: # positive/total #
- L6. External iliac: Right: # positive/total # Left: # positive/total #
- L7. Para-aortic: Right: # positive/total # Left: # positive/total #
- L8. Inguinal: Right: # positive/total # Left: # positive/total #
- M. Extracapsular lymph node spread #
- 1. Yes
- 2. No
- N. TNM Stage: T 3C N X M X
- O. FIGO Stage: IIIC

Source: NCI Genomic Data Commons file fcad23a6-ccd3-4dc1-9e44-2a1b00d924b2 (TCGA-61-1914.B634B2CF-9E8D-4DD4-8442-337C22522A43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).